Gene-level copy-number profile of tumor specimen TCGA-LN-A49Y-01A from TCGA case TCGA-LN-A49Y, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.0 years (28,125 days).
Specimen TCGA-LN-A49Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.21e32fd0-1663-41f5-b746-32718754430f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bd78aea-4524-42b1-aac4-d50680bf0d88

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 78; copy number 1: 16,945; copy number 2: 36,241; copy number 3: 4,196; copy number 4: 438; copy number 5: 189; copy number 6: 924; copy number 7: 112; copy number 8: 117; copy number 9: 208; copy number 10: 113; copy number 13: 42; copy number 14: 114; copy number 16: 25; copy number 17: 20; copy number 18: 19; copy number 22: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49Y-01A-11D-A25X-01): tumor purity 0.95, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 78 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,453,802–21,559,900, 1 gene (within-gene range 0–1): MIR31HG.
- chr9:21,512,115–23,898,054, 34 genes: MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2.
- chr9:30,388,935–31,645,160, 15 genes (within-gene range 0–1): LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr20:23,356,594–23,826,729, 28 genes: LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,918 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,523,538–198,222,513, 933 genes, copy number 5–8 (broad region; genes not listed).
- chr7:53,187,388–62,275,678, 170 genes, copy number 9–17 (broad region; genes not listed).
- chr7:87,503,017–87,713,323, 1 gene, copy number 10 (within-gene range 3–10): ABCB1.
- chr7:87,627,548–99,534,700, 199 genes, copy number 9–22 (broad region; genes not listed).
- chr7:111,726,110–112,206,407, 1 gene, copy number 16 (within-gene range 1–16): DOCK4.
- chr7:111,808,516–113,494,870, 27 genes, copy number 16–22: DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1, AC073348.2.
- chr8:37,326,575–38,704,855, 54 genes, copy number 6: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr8:39,522,976–40,107,935, 12 genes, copy number 6 (within-gene range 1–6): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1.
- chr8:40,530,590–42,555,195, 44 genes, copy number 5–9 (within-gene range 1–9): ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr11:41,993,381–45,044,053, 51 genes, copy number 7–18 (within-gene range 4–18): LINC02745, LINC02740, AC109810.1, AC009643.2, AC009643.1, HNRNPKP3, API5, AC087276.2, Y_RNA, TTC17, AC087276.3, AC087276.1, RN7SKP287, PPIAP41, CTBP2P6, AC068205.1, MIR670, MIR670HG, AC068205.2, MIR129-2, HSD17B12, AC068205.3, RPL23AP63, PHBP2, AC068205.4, AC087521.2, AC087521.4, ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1, ACCSL, ACCS, AC134775.1, EXT2, ALX4, AC010768.4, AC010768.3, CD82, AC010768.1, AC010768.2, RPL34P22, AC104010.1, LINC02704, TSPAN18-AS1, TSPAN18, TP53I11, LINC02685, AC068858.1.
- chr11:67,414,968–70,436,584, 114 genes, copy number 6–8 (broad region; genes not listed).
- chr11:70,477,277–70,647,562, 4 genes, copy number 8: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr11:78,215,293–78,418,348, 1 gene, copy number 5 (within-gene range 3–5): GAB2.
- chr11:78,324,758–83,286,407, 58 genes, copy number 5–8: AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B.
- chr11:125,955,796–135,075,908, 143 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr17:77,722,872–80,976,948, 97 genes, copy number 6 (broad region; genes not listed).
- chr20:21,125,983–21,389,825, 7 genes, copy number 5 (within-gene range 1–5): KIZ, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2.
- chr20:21,947,647–22,074,654, 2 genes, copy number 5 (within-gene range 1–5): AL109807.1, LINC01432.

Autosomal genes at a single copy (total copy number 1): 14,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
